Somatic mutation profile of tumor specimen TCGA-B5-A11L-01B (aliquot TCGA-B5-A11L-01B-21D-A13L-09) from TCGA case TCGA-B5-A11L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 71.5 years (26,120 days).
Specimen TCGA-B5-A11L-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3dbeb6b-a98f-42bc-81ee-a23faca46a55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11L-10A (Blood Derived Normal), aliquot TCGA-B5-A11L-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bad841f-99be-4c9c-833d-4affaa268ebd

The open-access MAF lists 120 somatic variants for this specimen: 91 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 28, Nonsense Mutation 6, Frame Shift Del 5, In Frame Del 3, Splice Site 2, Frame Shift Ins 1, In Frame Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912475, COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.419T>G p.L140* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | hotspot (GDC flag); catalogued as COSV64289095, COSV64298590; called by muse, mutect2, varscan2
- AJAP1 | c.504C>A p.D168E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100981921; called by muse, mutect2, varscan2
- ALPK2 | c.5126A>G p.E1709G | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV100864565; called by muse, mutect2, varscan2
- ARHGEF17 | c.6151C>T p.R2051* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as rs778190966, COSV99736231; called by muse, mutect2, varscan2
- ARID1A | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV100253458, COSV61375369; called by muse, mutect2, varscan2
- ATP4A | c.1947C>G p.S649R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99382862; called by muse, mutect2, varscan2
- BMP7 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV67780806, COSV99060160; called by muse, mutect2, varscan2
- C1QL3 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464754642, COSV100127019, COSV100127040; called by muse, mutect2, varscan2
- CAPN15 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs771759007, COSV99562664; called by muse, varscan2
- CBFA2T2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV100656210, COSV100656447; called by muse, mutect2, varscan2
- CCND1 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99919687; called by muse, mutect2, varscan2
- CDC16 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99373048; called by muse, mutect2, varscan2
- CDC25C | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs776011399, COSV100086825; called by muse, mutect2, varscan2
- CDC73 | c.564A>C p.K188N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66465887; called by muse, mutect2, varscan2
- CDH20 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.271); catalogued as rs528882646, COSV53008475; called by muse, mutect2, varscan2
- CDH3 | c.2280+1G>T p.X760_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99868801; called by muse, mutect2, varscan2
- CEP128 | c.1850C>A p.A617E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.206); catalogued as COSV99825409; called by muse, mutect2, varscan2
- CFTR | c.537A>T p.Q179H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99137880; called by muse, mutect2, varscan2
- CHD4 | c.2591G>A p.R864Q (on ENST00000357008 / NM_001363606.2; = p.R877Q on NM_001273.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58900818; called by muse, mutect2, varscan2
- COL11A1 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV100617565; called by mutect2, varscan2
- CRMP1 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs758401728, COSV61481541; called by muse, mutect2, varscan2
- CTPS1 | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV101009364; called by muse, mutect2, varscan2
- DDX58 | c.2775A>C p.K925N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100008381; called by muse, mutect2, varscan2
- DMD | c.7388C>G p.S2463C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100628427; called by muse, mutect2, varscan2
- DPYSL2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234022; called by muse, mutect2, varscan2
- DSC3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs750237973, COSV100844658; called by muse, mutect2, varscan2
- DYNC1LI2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs756767666, COSV99263064; called by muse, mutect2, varscan2
- FAM110B | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.103); catalogued as rs771272946, COSV64065706; called by muse, mutect2, varscan2
- FAM135A | c.494C>T p.S165F (on ENST00000370479 / NM_001351599.1; = p.S122F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99526313; called by muse, mutect2, varscan2
- FAM13B | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99221613; called by muse, mutect2, varscan2
- FAT3 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175548368, COSV53078119; called by muse, mutect2, varscan2
- GABRB3 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100160943; called by muse, mutect2, varscan2
- GRAP2 | c.26T>G p.F9C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703072; called by muse, mutect2, varscan2
- GRID2 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs182789669, COSV99943936; called by muse, mutect2, varscan2
- GRM6 | c.2370C>A p.Y790* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99179726; called by muse, mutect2, varscan2
- IRF5 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1284336147, COSV99977868; called by muse, mutect2, varscan2
- IRF9 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166537329, COSV100138223; called by muse, mutect2, varscan2
- JARID2 | c.2287G>A p.G763S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs372474171; called by muse, mutect2, varscan2
- MCM8 | c.2153G>C p.R718P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54510083, COSV54517164, COSV99495985; called by muse, mutect2, varscan2
- MED24 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1442230131, COSV62417434; called by muse, mutect2, varscan2
- MTCL1 | c.2476C>T p.R826W (on ENST00000306329 / NM_001378206.1; = p.R466W on NM_015210.4) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs115973534, COSV100095201; called by muse, mutect2, varscan2
- MTMR1 | c.1493C>A p.S498Y | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953135; called by muse, mutect2, varscan2
- MTOR | c.5941A>G p.K1981E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV63871327; called by muse, mutect2, varscan2
- MYO1C | c.1351G>A p.E451K (on ENST00000648651 / NM_001080779.2; = p.E416K on NM_033375.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs765250955, COSV63000020; called by muse, mutect2, varscan2
- NLRP8 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV52588414, COSV99405654; called by muse, mutect2, varscan2
- OR2T4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756078095, COSV63544824; called by muse, mutect2, varscan2
- OR5M1 | c.815A>T p.K272I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101591580; called by muse, mutect2, varscan2
- PAH | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as rs201245932, CM1511439; called by muse, mutect2, varscan2
- PARP14 | c.5194G>A p.A1732T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV101506313; called by muse, mutect2, varscan2
- PCDHGA12 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99341361; called by muse, mutect2, varscan2
- PEX1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as rs780349018, COSV50398917; called by muse, mutect2, varscan2
- PLP2 | c.324C>A p.N108K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100890183; called by muse, mutect2, varscan2
- POU4F3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV100047158; called by muse, mutect2, varscan2
- PPM1J | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751414157, COSV99588427; called by muse, mutect2, varscan2
- PPP2CA | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV99196044; called by muse, mutect2, varscan2
- PRPF40B | c.1075C>T p.R359C (on ENST00000380281; = p.R353C on NM_012272.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs760270847, COSV99980013; called by muse, mutect2, varscan2
- PTEN | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as rs1554825200, CM1310837, COSV64291436, COSV64298657, COSV64300002; called by muse, mutect2, varscan2
- PTGER4 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100201666; called by muse, mutect2, varscan2
- RFTN2 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99695825; called by muse, mutect2, varscan2
- RTN2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs143302045, COSV55594806; called by muse, mutect2, varscan2
- RYR2 | c.12926T>C p.I4309T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100772023; called by muse, mutect2, varscan2
- SARDH | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs145092538; called by muse, mutect2, varscan2
- SCAF4 | c.1336_1338del p.R447del | In Frame Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs776114607; called by pindel, varscan2
- SCN5A | c.3695G>A p.R1232Q (on ENST00000333535 / NM_198056.3; = p.R1231Q on NM_000335.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs199473206, CM100694, COSV61138843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV99918563; called by muse, mutect2, varscan2
- SLITRK4 | c.2287C>A p.L763I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.743); catalogued as COSV100567438; called by muse, mutect2, varscan2
- SMYD1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs186217134; called by muse, mutect2, varscan2
- SPOP | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV61653170; called by muse, mutect2, varscan2
- THSD1 | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51630054, COSV99319198; called by muse, varscan2
- TLE6 | c.505G>T p.G169C (on ENST00000246112 / NM_001143986.2; = p.G46C on NM_024760.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99858226, COSV99858382; called by muse, mutect2, varscan2
- TNNT2 | c.787A>G p.K263E (on ENST00000236918; = p.K260E on NM_000364.4) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99372441; called by muse, mutect2, varscan2
- TRAF6 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs368077395; called by muse, mutect2, varscan2
- TRRAP | c.7639C>T p.R2547W (on ENST00000359863 / NM_001244580.1; = p.R2529W on NM_003496.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs769337224, COSV100722693; called by muse, mutect2, varscan2
- TUT7 | c.1402T>A p.F468I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99463355; called by muse, mutect2, varscan2
- USH1G | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1247865819, COSV100140560; called by muse, mutect2, varscan2
- ZNF462 | c.3382G>A p.G1128R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99472700; called by muse, mutect2, varscan2
- ZNF626 | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV101656926, COSV101656999; called by muse, mutect2, varscan2
- ZNF8 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201979206, COSV99544447; called by mutect2, varscan2
- ALG3 | c.892del p.L298Sfs*23 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- ASAH2 | c.719del p.P240Qfs*42 | Frame Shift Del (DEL) | VAF 50/280 reads (18%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.992+1del p.X331_splice | Splice Site (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- F7 | c.316+4_316+22del | Splice Region (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- IFIT1 | c.683_684del p.Q228Rfs*2 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- ITGA2 | c.3309_3311dup p.N1104dup | In Frame Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1665_1685del p.E555_R562delinsD (on ENST00000521381 / NM_181523.3; = p.E285_R292delinsD on NM_181504.4) | In Frame Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel
- PLEKHG6 | c.2052_2055del p.L685Tfs*38 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- TBC1D25 | c.1214_1216del p.F405del | In Frame Del (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- USP39 | c.429_430del p.F143Lfs*17 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- USP53 | c.1571dup p.S525Efs*12 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2403C>T p.P801= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs536820757, COSV99566320; called by muse, mutect2, varscan2
- AC092143.1 | c.1489T>C p.L497= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100205968; called by muse, mutect2, varscan2
- ACTA1 | c.726C>T p.Y242= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV64203210; called by muse, mutect2, varscan2
- ADCY2 | c.3186A>C p.I1062= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100603449; called by muse, mutect2, varscan2
- ANKS1B | c.3027T>C p.D1009= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100228439; called by muse, varscan2
- AZIN2 | c.24G>A p.S8= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1317831615, COSV99613592; called by muse, mutect2, varscan2
- CEP72 | c.165T>A p.G55= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99375090; called by muse, mutect2, varscan2
- CNTNAP4 | c.1338C>T p.V446= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs557613459, COSV100272403; called by muse, mutect2
- CSMD2 | c.5919G>A p.E1973= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99592777; called by muse, mutect2, varscan2
- CTNND2 | c.1186C>A p.R396= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100479185; called by mutect2, varscan2
- DOP1A | c.6810C>G p.P2270= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99382504; called by muse, mutect2, varscan2
- ENTPD1 | c.654T>A p.S218= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100967640; called by muse, mutect2, varscan2
- EVPL | c.4098C>T p.P1366= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs752563754, COSV100043931; called by mutect2, varscan2
- FLG | c.9309C>G p.S3103= | Silent (SNP) | VAF 60/108 reads (56%) | catalogued as COSV100911859; called by muse, varscan2
- GARS1 | c.2091A>T p.A697= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101220220; called by muse, mutect2, varscan2
- HYDIN | c.9138C>G p.T3046= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs368515676; called by mutect2, varscan2
- KLHL31 | c.318G>A p.P106= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs186867536, COSV100911818; called by muse, mutect2, varscan2
- MAGEC1 | c.471T>G p.G157= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99596096; called by muse, mutect2
- MARCO | c.87C>T p.F29= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs759366698, COSV59057298; called by mutect2, varscan2
- MARK2 | c.960C>T p.L320= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100158903; called by muse, mutect2, varscan2
- MCF2L | c.3144C>T p.G1048= (on ENST00000375608; = p.G1016= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99995996; called by muse, mutect2, varscan2
- OR52E4 | c.192C>T p.F64= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV100389308; called by muse, mutect2, varscan2
- RFTN2 | c.147A>C p.S49= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99695743, COSV99695824; called by muse, mutect2, varscan2
- SEMA5A | c.2031C>A p.R677= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV101228545; called by muse, mutect2, varscan2
- SLC44A5 | c.1395C>T p.L465= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100902275; called by muse, mutect2, varscan2
- UGT2B7 | c.1332A>G p.K444= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100535258; called by muse, mutect2, varscan2
- WFIKKN1 | c.225C>T p.C75= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs765174836, COSV99937892; called by muse, mutect2, varscan2
- ZMYM3 | c.1947C>T p.S649= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs747782101, COSV100078166; called by muse, mutect2, varscan2
- MCM9 | c.1150+9T>A | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99995900; called by muse, mutect2, varscan2
